Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00U, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00U-01A (Primary Tumor).

Sample ID #

Diagnosis:

Extended hemicolectomy specimen with two invasive, moderately differentiated adenocarcinomas with infiltration of the pericolic fatty tissue and status following endoscopic resection of a further adenocarcinoma. Multiple tubular adenomas with moderate dysplasia (synonym: low-grade intra-epithelial neoplasia). Two lymph node metastases. Tumor-free resection margins in the region of the mucosa. Tumor-free omentum.

Tumor classification: adenocarcinoma, G2 pT3 (mult/3) n1 (2/116) L0 V0 R0

1CD-0-3

adenocarcinoma, NOS 8140/3

Site: ~~ascending~~
ascending colon C18.2 for 3/30/11

Primary Malignancy History		X

Source: NCI Genomic Data Commons file e93b90e3-c718-4153-8255-21c7b444e2fd (TCGA-AA-A00U.670DA42C-A894-45FC-9785-17BB52AE81F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).